Somatic mutation profile of tumor specimen C3N-01090-04 (aliquot CPT0212770006) from CPTAC case C3N-01090, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G1.
Specimen C3N-01090-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2708ea41-8eba-4696-a105-117c3bee2e1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01090-71 (Blood Derived Normal), aliquot CPT0212840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a45f7d70-5f14-4a2c-ae83-a46f8ffcc867

The open-access MAF lists 91 somatic variants for this specimen: 61 protein-altering or splice-affecting, 18 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 18, Frame Shift Del 8, Intron 5, Nonsense Mutation 4, Splice Site 3, 5'Flank 3, In Frame Del 2, Frame Shift Ins 2, 5'UTR 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.262T>C p.W88R | Missense Mutation (SNP) | VAF 171/681 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1553619431, CM031392, CM951278, COSV56542744, COSV56546104, COSV56548816; ClinVar: pathogenic; called by muse, varscan2
- AL035460.1 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 66/318 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.329); catalogued as COSV63028057; called by muse, mutect2, varscan2
- ARMC9 | c.1163G>C p.R388P | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV63022505; called by muse, mutect2, varscan2
- CAMK2G | c.604del p.V202Sfs*40 | Frame Shift Del (DEL) | VAF 33/146 reads (23%) | catalogued as rs36042365; called by mutect2, pindel, varscan2
- CSRP1 | c.505+1G>A p.X169_splice | Splice Site (SNP) | VAF 43/203 reads (21%) | catalogued as rs1553300790; called by muse, varscan2
- DELE1 | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs769560236; called by muse, mutect2, varscan2
- FH | c.489A>T p.E163D | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV100845030; called by muse, mutect2, varscan2
- GAB4 | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.515); catalogued as COSV68752969; called by muse, mutect2, varscan2
- KANSL1L | c.848G>C p.G283A | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV55998245; called by muse, mutect2, varscan2
- LRRC49 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.34); catalogued as rs1159247773; called by muse, mutect2
- MUC17 | c.4297G>T p.A1433S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1473924638, COSV60301245; called by muse, mutect2, varscan2
- PLEKHG3 | c.1576_1578del p.E526del (on ENST00000394691; = p.E582del on NM_001308147.2) | In Frame Del (DEL) | VAF 44/264 reads (17%) | catalogued as rs1443793802; called by pindel, varscan2
- PRAMEF19 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 219/1178 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs753459941; called by muse, mutect2, varscan2
- RAD54L | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 126/634 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1269019049, COSV64336708; called by muse, mutect2, varscan2
- RGS12 | c.2123G>C p.R708T | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369968915; called by muse, mutect2, varscan2
- RTCA | c.747T>G p.I249M | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV99559574; called by muse, mutect2, varscan2
- SCN2A | c.2828G>A p.W943* | Nonsense Mutation (SNP) | VAF 82/636 reads (13%) | catalogued as rs1553579510; called by muse, mutect2, varscan2
- SLC25A52 | c.229G>A p.D77N (on ENST00000672005; = p.D67N on NM_001034172.4) | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV52502096; called by muse, mutect2, varscan2
- SOX18 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1442431117; called by muse, mutect2, varscan2
- TNFAIP8 | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 71/439 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs755144287; called by muse, mutect2, varscan2
- ADGRF5 | c.4019G>A p.S1340N | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- AKR1A1 | c.521G>A p.S174N | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CDHR1 | c.805G>T p.V269F | Missense Mutation (SNP) | VAF 62/310 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- CFAP92 | c.3206T>A p.V1069E | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP2R1 | c.429T>G p.S143R | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DENND1B | c.1350+1G>T p.X450_splice | Splice Site (SNP) | VAF 34/188 reads (18%) | called by muse, mutect2, varscan2
- DLEC1 | c.40T>C p.S14P | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2
- DOCK8 | c.871T>C p.Y291H | Missense Mutation (SNP) | VAF 77/420 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EML6 | c.4703T>A p.L1568H | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- FANCL | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FASTK | c.888del p.F296Lfs*24 | Frame Shift Del (DEL) | VAF 32/172 reads (19%) | called by mutect2, pindel
- FAT2 | c.11570del p.V3857Gfs*10 | Frame Shift Del (DEL) | VAF 70/544 reads (13%) | called by mutect2, pindel, varscan2
- FCGR3B | c.374A>C p.H125P | Missense Mutation (SNP) | VAF 75/368 reads (20%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- FNIP2 | c.2708_2716del p.E903_C905del | In Frame Del (DEL) | VAF 39/265 reads (15%) | called by mutect2, pindel, varscan2
- GALR2 | c.1098dup p.C367Lfs*19 | Frame Shift Ins (INS) | VAF 17/101 reads (17%) | called by mutect2, pindel, varscan2
- HMCN1 | c.10994del p.T3665Nfs*20 | Frame Shift Del (DEL) | VAF 68/435 reads (16%) | called by mutect2, pindel, varscan2
- NDST1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 94/680 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NDST1 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 97/686 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP205 | c.4891C>G p.L1631V | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- OBSL1 | c.547C>G p.R183G | Missense Mutation (SNP) | VAF 106/454 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- OR56B4 | c.78del p.H27Mfs*11 | Frame Shift Del (DEL) | VAF 32/172 reads (19%) | called by mutect2, pindel, varscan2
- OSCAR | c.70+1G>A p.X24_splice | Splice Site (SNP) | VAF 31/195 reads (16%) | called by muse, mutect2, varscan2
- PBRM1 | c.2688del p.K896Nfs*19 | Frame Shift Del (DEL) | VAF 37/185 reads (20%) | called by mutect2, pindel, varscan2
- PCNX3 | c.4472G>A p.S1491N | Missense Mutation (SNP) | VAF 76/334 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2
- PCSK1 | c.1909A>C p.K637Q | Missense Mutation (SNP) | VAF 53/423 reads (13%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDLIM5 | c.1677G>A p.W559* | Nonsense Mutation (SNP) | VAF 26/173 reads (15%) | called by muse, mutect2, varscan2
- PEX3 | c.614T>A p.L205* | Nonsense Mutation (SNP) | VAF 25/159 reads (16%) | called by muse, mutect2, varscan2
- PHKA1 | c.2531G>A p.C844Y | Missense Mutation (SNP) | VAF 90/293 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PHKA1 | c.2530T>C p.C844R | Missense Mutation (SNP) | VAF 89/293 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PLXNA1 | c.4763C>G p.A1588G | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PPP1R13L | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- PTPRE | c.334T>A p.Y112N | Missense Mutation (SNP) | VAF 65/353 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- RABEP1 | c.1276_1279del p.Y426Kfs*17 | Frame Shift Del (DEL) | VAF 102/523 reads (20%) | called by mutect2, pindel, varscan2
- RBM11 | c.567G>T p.W189C | Missense Mutation (SNP) | VAF 68/407 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.133); called by muse, varscan2
- RNF224 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (1); called by muse, mutect2, varscan2
- SCRN1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 65/425 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCX | c.336dup p.K113Qfs*3 | Frame Shift Ins (INS) | VAF 98/635 reads (15%) | called by mutect2, pindel, varscan2
- SDC2 | c.376del p.E126Rfs*21 | Frame Shift Del (DEL) | VAF 19/150 reads (13%) | called by mutect2, pindel, varscan2
- STIM1 | c.1860C>G p.S620R | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- SWT1 | c.2291T>A p.I764N | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TLR2 | c.1918T>A p.C640S | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANO3 | c.768C>T p.N256= | Silent (SNP) | VAF 44/205 reads (21%) | called by muse, mutect2, varscan2
- CARMIL2 | c.3273C>T p.P1091= | Silent (SNP) | VAF 21/160 reads (13%) | catalogued as rs1404205576; called by muse, mutect2, varscan2
- DDX10 | c.492A>T p.V164= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs766022467; called by muse, mutect2, varscan2
- DLGAP1 | c.1527G>T p.V509= | Silent (SNP) | VAF 99/521 reads (19%) | called by muse, mutect2, varscan2
- GNAL | c.351G>A p.Q117= | Silent (SNP) | VAF 13/147 reads (9%) | called by muse, mutect2
- HOXB6 | c.231G>C p.A77= | Silent (SNP) | VAF 52/271 reads (19%) | called by muse, mutect2, varscan2
- MYH9 | c.4764C>T p.V1588= | Silent (SNP) | VAF 81/449 reads (18%) | catalogued as rs1279085038; called by muse, mutect2, varscan2
- MYO1C | c.318C>A p.G106= (on ENST00000648651 / NM_001080779.2; = p.G71= on NM_033375.5) | Silent (SNP) | VAF 52/281 reads (19%) | catalogued as COSV62999905; called by muse, mutect2, varscan2
- NOX3 | c.679C>A p.R227= | Silent (SNP) | VAF 28/310 reads (9%) | catalogued as COSV50149220; called by muse, mutect2
- P2RY1 | c.765G>A p.R255= | Silent (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- PDE1C | c.1362C>A p.I454= | Silent (SNP) | VAF 33/185 reads (18%) | catalogued as COSV58528346; called by muse, mutect2, varscan2
- PDIA6 | c.36C>T p.S12= | Silent (SNP) | VAF 49/319 reads (15%) | called by muse, mutect2, varscan2
- PLPPR2 | c.435C>T p.N145= | Silent (SNP) | VAF 82/372 reads (22%) | called by muse, mutect2, varscan2
- PRKDC | c.5151C>T p.L1717= | Silent (SNP) | VAF 58/351 reads (17%) | catalogued as rs533442987; called by muse, mutect2, varscan2
- PRR12 | c.3453T>C p.H1151= (on ENST00000615927; = p.H1972= on NM_020719.3) | Silent (SNP) | VAF 50/336 reads (15%) | called by mutect2, varscan2
- RTL1 | c.2094G>A p.K698= | Silent (SNP) | VAF 39/196 reads (20%) | called by muse, mutect2, varscan2
- TET1 | c.5532A>G p.A1844= | Silent (SNP) | VAF 11/257 reads (4%) | called by muse, mutect2
- ZNF417 | c.867C>T p.V289= | Silent (SNP) | VAF 68/381 reads (18%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500453 C>A | 5'Flank (SNP) | VAF 49/362 reads (14%) | called by muse, mutect2, varscan2
- COL18A1 | chr21:45455529 C>G | 5'Flank (SNP) | VAF 46/354 reads (13%) | catalogued as COSV100700684; called by muse, mutect2, varscan2
- CSPP1 | c.330+545T>G | Intron (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- DIP2C | c.85+39096T>A | Intron (SNP) | VAF 88/519 reads (17%) | catalogued as rs1401360667; called by muse, mutect2, varscan2
- GRHL1 | c.-67C>A | 5'UTR (SNP) | VAF 73/370 reads (20%) | called by muse, mutect2, varscan2
- JAG1 | chr20:10636375 C>G | 3'Flank (SNP) | VAF 29/156 reads (19%) | catalogued as rs1176995720; called by muse, mutect2, varscan2
- LINC01545 | n.337G>A | RNA (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- MATR3 | c.*468G>T | 3'UTR (SNP) | VAF 50/416 reads (12%) | called by muse, mutect2, varscan2
- PFKP | c.112+1652G>A | Intron (SNP) | VAF 39/203 reads (19%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159934 T>G | 5'Flank (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2
- TM7SF3 | c.91+1356C>T | Intron (SNP) | VAF 27/209 reads (13%) | catalogued as rs1182024216; called by muse, mutect2, varscan2
- TNPO2 | c.-13-76_-13-75del | Intron (DEL) | VAF 58/394 reads (15%) | called by pindel, varscan2
